Surgical pathology report (de-identified scan), TCGA case TCGA-FP-8211, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-8211-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology

Histopathological Examination

Pre-Op Diagnosis : Esophageal Cancer
Order Physician :
Specimens : Esophagus, nos
Frozen Diagnosis : Block# : A-1
Re-Ex? :
FS-Diag : Margins of resection free of tumor
Comment : none
Block# : A-2
Re-Ex? :
FS-Diag : Margins of resection free of tumor
Comment : none

Report : GROSS EXAMINATION:

The specimen is received fresh in a container labeled with the name of the patient and labeled as esophagus, NOS. The specimen consists of an esophagus and partial stomach segment. The esophagus measures 10.5 cm in length and ranges from 4-6 cm in circumference. The stomach measures 8.5 cm in length and ranges from 5 to 10.2 cm in circumference. An obstructive mass located at the gastroesophageal junction measures 3.4 x 3.4 x 3.7 cm. The mass is polypoid and ulcerated and encompasses approximately 99% of the GE junction. The mass is 8.9 cm from the proximal margin and 5 cm from the distal margin. The mass extends through the wall to within 0.1 cm of the adventitial margin, which is inked orange. Proximal and distal margins are submitted in blocks 1-2 respectively for frozen section.

FROZEN SECTION DIAGNOSIS: A1: Esophageal margin free of tumor.
A2: Gastric margin free of tumor. (

The adventitial margin is sampled in blocks 3 and 4. Sections of the mass are submitted in blocks 5-8. An additional ulcerated mass located in the stomach one cm distal from the larger mass measures 2.2 cm in width and 0.9 cm in thickness. The second tumor measures 2 cm from the

[page 2 of 3]
closer gastric margin and 12 cm from the farther esophageal margin. Representative sections are submitted in blocks 9-10. A random section of proximal esophagus is submitted in block 11. A random section of mid esophagus is submitted in block 12. Possible lymph nodes are submitted as follows: Three in block 13, one in block 14, one in block 15. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

Esophagus, esophagogastrectomy:

- Esophagogastric adenocarcinoma, grade 2, 3.7 cm in greatest dimension.
- Tumor invades through muscularis propria into periesophageal soft tissue.
- Radial (adventitial) margin is focally positive.
- Proximal and distal resection margins are negative.
- Separate gastric adenocarcinoma, grade 2, 2.2 cm in greatest dimension.
- Tumor invades through muscularis propria into periesophageal soft tissue.
- Proximal, distal, and radial resection margins are negative.
- Two of seven lymph nodes, positive for metastatic adenocarcinoma (2/7).
- Intradepartmental consultation obtained.
- See cancer case summary checklist below.
- [REDACTED]

CANCER CASE SUMMARY CHECKLIST

ESOPHAGUS: Esophagogastrectomy (Version 3.1.0.0)

SPECIMEN: Esophagus, proximal stomach

PROCEDURE: Esophagogastrectomy

TUMOR SITE: Esophagogastric junction (larger mass); proximal stomach (separate smaller mass)

RELATIONSHIP OF TUMOR TO ESOPHAGOGASTRIC JUNCTION: Tumor midpoint is located at the esophagogastric junction (larger tumor)

Distance of tumor center from esophagogastric junction: 0 cm

TUMOR SIZE:

Greatest dimension: 3.7 cm

Additional dimensions: 3.4 x 3.4 cm

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: Grade 2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION: Tumor invades through the muscularis propria into periesophageal soft tissue (adventitia)

MARGINS: Proximal margin: Uninvolved by invasive carcinoma or dysplasia.

Distal margin: Uninvolved by invasive carcinoma or dysplasia.

Circumferential (adventitial) margin: Involved by invasive carcinoma.

TREATMENT EFFECT (CARCINOMA TREATED W/ NEOADJUVANT THERAPY): No prior treatment

[page 3 of 3]
LYMPH-VASCULAR INVASION: Present
PATHOLOGIC STAGING (pTNM):
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT3: Tumor invades adventitia
Regional Lymph Nodes (pN): pN1: Regional lymph node
metastasis involving 1 to 2 nodes.
Number of lymph nodes examined: 7
Number of lymph nodes involved: 2
Distant Metastasis (pM): Not applicable.
ADDITIONAL PATHOLOGIC FINDINGS: Separate ulcerated gastric
adenocarcinoma, grade 2, 2.2 cm in greatest dimension,
invading adventitia with negative margins.
PATHOLOGIC STAGE SUMMARY: mpT3N1G2

Electronically Signed by:

Source: NCI Genomic Data Commons file a5c54eb2-8ee7-41aa-989a-1ff02b5690bb (TCGA-FP-8211.54B34D85-D6D2-4C35-B43B-F7B10B99B651.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).